Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3833, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3833-01A (Primary Tumor).

Findings and diagnosis relating to the problem

The material at hand is an invasive adenocarcinoma of the colon in block A, poorly differentiated, tending toward partial neuroendocrine differentiation, with penetration of all wall layers and clear vascular infiltration (corresponding to p T 3, L1, V1). Otherwise, in relation to the mucosa resection margins:

- orally - mucosa of ileum type and
- distally - mucosa of colon type
- in relation to the ligature region – local fatty connective tissue with proper vascular sections
- relating to the appendix – chronic recurrent, partially scarring appendicitis with clear activation of the lymph follicle, and
- relating to the lymph nodes – chronic resorptive lymphadenitis, also with clear activation of the lymph follicle

Tumor classification:

ICDO-DA M 8140/3

G 3

p T 3, L1, V1, p N 0 consistent with R 0. *N (0/12)*

Source: NCI Genomic Data Commons file 795cfeb7-4b33-467c-82b1-d897d2875734 (TCGA-AA-3833.701E11C7-9FA9-4D45-9D35-1FAE3C3827AE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).